Somatic mutation profile of tumor specimen 0DGRHL from CCDI case PBBTPN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of head, face, and neck; Age at diagnosis: 13.4 years (4,885 days).
Specimen 0DGRHL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63465c05-48f3-470d-93d6-c8b1227d1030.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGRHS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8c5fe4d-7cf7-43db-a6c6-7136bff85c49

The open-access MAF lists 169 somatic variants for this specimen: 115 protein-altering or splice-affecting, 28 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 105, Silent 28, Intron 15, 5'UTR 5, 3'UTR 5, Nonsense Mutation 4, Splice Site 3, Frame Shift Del 1, 3'Flank 1, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PEX1 | c.2383C>T p.R795* | Nonsense Mutation (SNP) | VAF 218/1069 reads (20%) | catalogued as rs61750418, CM991032, COSV99952132; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 409/851 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRG4 | c.2043T>A p.N681K | Missense Mutation (SNP) | VAF 162/808 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as rs764584377; called by mutect2, varscan2
- AGBL1 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 244/944 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs951955069; called by muse, mutect2, varscan2
- AIMP1 | c.560G>A p.R187K | Missense Mutation (SNP) | VAF 298/1082 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as rs1009406376; called by muse, mutect2, varscan2
- AKR1C1 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 559/2189 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as rs138128200; called by muse, varscan2
- APC2 | c.3205C>T p.R1069* | Nonsense Mutation (SNP) | VAF 86/314 reads (27%) | catalogued as COSV52017135; called by muse, mutect2, varscan2
- APOB | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 312/825 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.143); catalogued as rs201606169; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARSJ | c.1578C>A p.F526L | Missense Mutation (SNP) | VAF 74/957 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV59538638; called by muse, mutect2
- ATP1A3 | c.1427G>A p.R476H (on ENST00000545399 / NM_001256214.2; = p.R463H on NM_152296.5) | Missense Mutation (SNP) | VAF 106/1305 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs782499746; ClinVar: likely benign; called by muse, mutect2
- CACNA1D | c.2621+1G>A p.X874_splice (on ENST00000350061 / NM_001128840.3; = p.X894_splice on NM_000720.4) | Splice Site (SNP) | VAF 35/686 reads (5%) | catalogued as COSV55444715; called by muse, mutect2
- CACNA1I | c.4754G>A p.R1585H | Missense Mutation (SNP) | VAF 362/1315 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1040992747, COSV60809705; called by muse, mutect2, varscan2
- CALR | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 354/1441 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs780575677; called by muse, mutect2, varscan2
- CCDC157 | c.649G>T p.A217S | Missense Mutation (SNP) | VAF 259/959 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.421); catalogued as COSV57841659; called by mutect2, varscan2
- CLIC6 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 129/380 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.149); catalogued as rs930714318; called by muse, mutect2, varscan2
- CNTNAP3B | c.53A>G p.Q18R | Missense Mutation (SNP) | VAF 185/1193 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs1243975563; called by muse, mutect2, varscan2
- CRNN | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 440/1977 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs768081258; called by muse, mutect2, varscan2
- EEA1 | c.167T>G p.L56R | Missense Mutation (SNP) | VAF 42/1334 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59282080; called by muse, mutect2
- ERBIN | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 286/1403 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs764832257; called by mutect2, varscan2
- FAM135A | c.2063T>C p.L688P (on ENST00000370479 / NM_001351599.1; = p.L475P on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 150/505 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.125); catalogued as rs1419540739; called by muse, mutect2, varscan2
- FAM83C | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 187/1144 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs777921694, COSV65584721; called by muse, mutect2, varscan2
- FBXO5 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 317/1064 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV57670501; called by muse, mutect2, varscan2
- GUCY2D | c.1828C>G p.L610V | Missense Mutation (SNP) | VAF 297/595 reads (50%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.007); catalogued as rs779224998; called by muse, mutect2, varscan2
- HIPK2 | c.1445C>T p.T482M | Missense Mutation (SNP) | VAF 119/729 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.91); catalogued as rs753352107, COSV61232538; called by muse, mutect2, varscan2
- HSPB8 | c.388C>A p.Q130K | Missense Mutation (SNP) | VAF 146/605 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV99931254; called by muse, mutect2, varscan2
- KLF18 | c.3020G>A p.R1007H | Missense Mutation (SNP) | VAF 167/1029 reads (16%) | SIFT deleterious (0); catalogued as rs376287364; called by muse, mutect2, varscan2
- MASP1 | c.398C>A p.A133D | Missense Mutation (SNP) | VAF 487/1416 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777281636, COSV51457741; called by mutect2, varscan2
- MGAT5 | c.814G>A p.V272I | Missense Mutation (SNP) | VAF 156/1043 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs547381763, COSV56095090, COSV56102677; called by muse, mutect2, varscan2
- MMP16 | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 190/1799 reads (11%) | catalogued as COSV54182752; called by muse, mutect2, varscan2
- MPP1 | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 99/1059 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101053922; called by muse, mutect2
- MUC17 | c.2803C>G p.P935A | Missense Mutation (SNP) | VAF 188/1637 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as rs1187226408, COSV100072727, COSV60280117; called by muse, mutect2, varscan2
- MYBPC3 | c.1128C>A p.S376R | Missense Mutation (SNP) | VAF 140/937 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.148); catalogued as rs1555122453; ClinVar: uncertain significance; called by mutect2, varscan2
- MYO9B | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 135/597 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.082); catalogued as rs776771761, COSV68282533; called by muse, mutect2, varscan2
- NHSL2 | c.2047G>A p.G683S (on ENST00000510661; = p.G1049S on NM_001013627.2) | Missense Mutation (SNP) | VAF 203/1309 reads (16%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.003); catalogued as rs755673772, COSV65453660, COSV65453776; called by muse, mutect2, varscan2
- NT5E | c.5G>A p.C2Y | Missense Mutation (SNP) | VAF 52/774 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as rs1275223015; called by muse, mutect2
- NYNRIN | c.953C>G p.A318G | Missense Mutation (SNP) | VAF 428/787 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.24); catalogued as rs772650230; called by muse, mutect2, varscan2
- OR2T4 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 461/1327 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.127); catalogued as rs753722891, COSV63544854; called by muse, mutect2, varscan2
- PCDHA11 | c.1438G>T p.D480Y | Missense Mutation (SNP) | VAF 58/1062 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100253417; called by muse, mutect2
- PHKA1 | c.3265G>A p.G1089R | Missense Mutation (SNP) | VAF 193/999 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as COSV100263623; called by muse, mutect2, varscan2
- PHKA2 | c.3347A>C p.H1116P | Missense Mutation (SNP) | VAF 184/667 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs1364427002; called by muse, mutect2, varscan2
- PLEC | c.13024A>T p.I4342F (on ENST00000322810 / NM_201380.4; = p.I4232F on NM_000445.5) | Missense Mutation (SNP) | VAF 385/1620 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV59655260; called by muse, mutect2, varscan2
- PSCA | c.78C>G p.C26W | Missense Mutation (SNP) | VAF 339/2683 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100008160, COSV56653057; called by muse, mutect2, varscan2
- RBM41 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 227/1548 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.538); catalogued as rs769714202, COSV99179841; called by muse, mutect2, varscan2
- RELCH | c.2591G>A p.R864H | Missense Mutation (SNP) | VAF 216/798 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.199); catalogued as rs766145734, COSV56883989, COSV56884489; called by muse, mutect2, varscan2
- RIMS1 | c.3856T>A p.L1286I | Missense Mutation (SNP) | VAF 317/1272 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs930435911; called by muse, mutect2, varscan2
- SEZ6L2 | c.2710C>T p.R904W (on ENST00000308713 / NM_001114099.3; = p.R847W on NM_012410.4) | Missense Mutation (SNP) | VAF 29/632 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs938870775, COSV100435944; called by muse, mutect2
- SIGLEC9 | c.1241C>A p.P414Q | Missense Mutation (SNP) | VAF 200/1041 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV51582889; called by muse, mutect2, varscan2
- THSD1 | c.838A>G p.R280G | Missense Mutation (SNP) | VAF 163/552 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1318241342; called by muse, mutect2, varscan2
- TNFAIP8L2 | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 198/868 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs749741483, COSV64423268; called by muse, mutect2, varscan2
- TNS3 | c.1202G>C p.R401T | Missense Mutation (SNP) | VAF 334/1694 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as rs1392400694; called by muse, mutect2, varscan2
- TRIM49D1 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 50/408 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs757772073; called by mutect2, varscan2
- TUBE1 | c.809C>T p.T270M | Missense Mutation (SNP) | VAF 230/896 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376900146; called by muse, mutect2, varscan2
- WDR72 | c.2133G>C p.E711D | Missense Mutation (SNP) | VAF 306/1175 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV64749862; called by muse, varscan2
- YIPF2 | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 200/830 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs371244312; called by muse, mutect2, varscan2
- ZFP14 | c.395A>G p.E132G | Missense Mutation (SNP) | VAF 85/1444 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV54202733, COSV54203830; called by muse, mutect2
- ZIC1 | c.1063G>A p.V355M | Missense Mutation (SNP) | VAF 445/1784 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV51551901; called by muse, mutect2, varscan2
- ZNF48 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 44/490 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.18); catalogued as rs760366010, COSV60782387; called by muse, mutect2
- ACVR1 | c.842T>G p.L281* | Nonsense Mutation (SNP) | VAF 96/1950 reads (5%) | called by muse, mutect2
- AKAP10 | c.664G>A p.G222R | Missense Mutation (SNP) | VAF 68/1096 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- ANO9 | c.2263G>A p.G755S | Missense Mutation (SNP) | VAF 164/720 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARHGAP27 | c.1252G>A p.V418M (on ENST00000428638 / NM_001282290.1; = p.V77M on NM_199282.3) | Missense Mutation (SNP) | VAF 276/476 reads (58%) | SIFT tolerated (0.23); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- BTK | c.400T>A p.Y134N | Missense Mutation (SNP) | VAF 182/912 reads (20%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- C12orf29 | c.715T>C p.S239P | Missense Mutation (SNP) | VAF 339/1139 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- CEP83 | c.899A>C p.K300T | Missense Mutation (SNP) | VAF 186/767 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- CHAT | c.423G>T p.Q141H | Missense Mutation (SNP) | VAF 236/911 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- COL14A1 | c.2512T>A p.S838T | Missense Mutation (SNP) | VAF 253/1775 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CRHBP | c.822A>T p.K274N | Missense Mutation (SNP) | VAF 241/1123 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- CTTNBP2 | c.531G>C p.E177D | Missense Mutation (SNP) | VAF 862/2177 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DAAM1 | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 315/1617 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- DACT2 | c.1894C>A p.P632T | Missense Mutation (SNP) | VAF 21/429 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.095); called by muse, mutect2
- DCAF1 | c.2129A>C p.K710T | Missense Mutation (SNP) | VAF 31/747 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.037); called by muse, mutect2
- DCDC1 | c.2464C>G p.L822V | Missense Mutation (SNP) | VAF 218/1232 reads (18%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- DENND2B | c.724G>C p.E242Q | Missense Mutation (SNP) | VAF 150/831 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- DGKI | c.858T>G p.C286W | Missense Mutation (SNP) | VAF 172/1414 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLL3 | c.296C>A p.P99H | Missense Mutation (SNP) | VAF 115/721 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- DNAH11 | c.7236G>T p.W2412C | Missense Mutation (SNP) | VAF 204/1030 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- DNAH3 | c.4074G>C p.R1358S | Missense Mutation (SNP) | VAF 139/523 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- E4F1 | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 202/679 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- EIF2A | c.1099C>G p.P367A | Missense Mutation (SNP) | VAF 310/1531 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- FFAR4 | c.1046T>A p.I349N | Missense Mutation (SNP) | VAF 230/846 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.168); called by mutect2, varscan2
- GPR32 | c.521C>A p.S174Y | Missense Mutation (SNP) | VAF 131/673 reads (19%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- GPRIN1 | c.1355C>G p.S452C | Missense Mutation (SNP) | VAF 165/675 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- GRIA4 | c.1736A>G p.E579G | Missense Mutation (SNP) | VAF 258/1144 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- KRT6C | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 156/952 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- MAGEC3 | c.1505A>C p.H502P | Missense Mutation (SNP) | VAF 181/1081 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.044); called by muse, varscan2
- MPV17L2 | c.358+1G>A p.X120_splice | Splice Site (SNP) | VAF 358/1529 reads (23%) | called by muse, mutect2, varscan2
- MS4A14 | c.1824C>A p.D608E | Missense Mutation (SNP) | VAF 228/1300 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.227); called by mutect2, varscan2
- NADK | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 24/568 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- NBAS | c.239T>G p.L80R | Missense Mutation (SNP) | VAF 284/701 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NKAP | c.468-1G>T p.X156_splice | Splice Site (SNP) | VAF 185/911 reads (20%) | called by muse, mutect2, varscan2
- P2RY8 | c.145T>C p.C49R | Missense Mutation (SNP) | VAF 36/1046 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); called by muse, mutect2
- PCDHA11 | c.1504G>A p.A502T | Missense Mutation (SNP) | VAF 159/651 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PKDREJ | c.4717C>T p.P1573S | Missense Mutation (SNP) | VAF 249/853 reads (29%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- PLEKHA8 | c.1123A>C p.N375H | Missense Mutation (SNP) | VAF 180/1042 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- POLR2A | c.1598C>T p.P533L | Missense Mutation (SNP) | VAF 263/614 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRICKLE3 | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 230/1325 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- RGS22 | c.266A>G p.K89R | Missense Mutation (SNP) | VAF 265/2100 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RPGRIP1L | c.2318C>T p.A773V | Missense Mutation (SNP) | VAF 89/694 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC16A10 | c.845T>A p.I282N | Missense Mutation (SNP) | VAF 294/946 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.853); called by mutect2, varscan2
- SLC7A1 | c.20T>G p.L7R | Missense Mutation (SNP) | VAF 137/574 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLCO3A1 | c.329G>T p.G110V | Missense Mutation (SNP) | VAF 15/411 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SORBS2 | c.612A>T p.K204N (on ENST00000284776 / NM_021069.5; = p.K250N on NM_003603.6) | Missense Mutation (SNP) | VAF 265/1171 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- SPEN | c.4179del p.R1394Efs*15 | Frame Shift Del (DEL) | VAF 258/1307 reads (20%) | called by mutect2, varscan2
- SSX4 | c.140T>C p.V47A | Missense Mutation (SNP) | VAF 190/2102 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2
- SSX4B | c.140T>C p.V47A | Missense Mutation (SNP) | VAF 97/1123 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2
- TASOR2 | c.2155A>C p.K719Q | Missense Mutation (SNP) | VAF 269/1017 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- TCP11X2 | c.855dup p.S286Qfs*19 | Frame Shift Ins (INS) | VAF 304/2440 reads (12%) | called by mutect2, varscan2
- TENM4 | c.7688G>C p.G2563A | Missense Mutation (SNP) | VAF 184/754 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.277); called by muse, mutect2
- TEX11 | c.1642T>A p.F548I (on ENST00000344304; = p.F533I on NM_031276.3) | Missense Mutation (SNP) | VAF 116/1164 reads (10%) | SIFT tolerated (0.81); PolyPhen benign (0.234); called by mutect2, varscan2
- TNRC18 | c.4435C>G p.L1479V | Missense Mutation (SNP) | VAF 234/1520 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBE2A | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 54/1452 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- USP33 | c.2147G>A p.S716N | Missense Mutation (SNP) | VAF 82/601 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.011); called by muse, varscan2
- VPS13B | c.8600G>A p.G2867E | Missense Mutation (SNP) | VAF 58/2049 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF442 | c.828T>A p.D276E | Missense Mutation (SNP) | VAF 184/856 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- ZNF653 | c.1648C>T p.H550Y | Missense Mutation (SNP) | VAF 34/791 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADGRF5 | c.2865C>A p.V955= | Silent (SNP) | VAF 219/908 reads (24%) | called by muse, mutect2, varscan2
- ARHGAP39 | c.897G>A p.S299= | Silent (SNP) | VAF 104/935 reads (11%) | called by muse, mutect2, varscan2
- ARHGEF10 | c.1452G>T p.A484= (on ENST00000398564; = p.A459= on NM_014629.4) | Silent (SNP) | VAF 390/1176 reads (33%) | catalogued as rs138680466; called by mutect2, varscan2
- ARMCX2 | c.1713T>C p.L571= | Silent (SNP) | VAF 34/1212 reads (3%) | called by muse, mutect2
- ASH1L | c.3873G>A p.L1291= | Silent (SNP) | VAF 34/1288 reads (3%) | called by muse, mutect2
- B3GNT3 | c.123G>A p.P41= | Silent (SNP) | VAF 157/731 reads (21%) | catalogued as rs761629826; called by muse, mutect2, varscan2
- CACNA1I | c.4755C>A p.R1585= | Silent (SNP) | VAF 323/1158 reads (28%) | catalogued as COSV100360661; called by mutect2, varscan2
- DISC1 | c.936T>C p.C312= | Silent (SNP) | VAF 241/1099 reads (22%) | called by muse, mutect2, varscan2
- FMO1 | c.621G>A p.A207= | Silent (SNP) | VAF 205/1099 reads (19%) | catalogued as rs367730433; called by muse, mutect2, varscan2
- GRID1 | c.1140G>T p.V380= | Silent (SNP) | VAF 167/640 reads (26%) | called by muse, mutect2, varscan2
- KCNK9 | c.942G>A p.P314= | Silent (SNP) | VAF 411/1392 reads (30%) | catalogued as rs140520381, COSV57287049; called by muse, mutect2, varscan2
- KMT2C | c.8754C>G p.L2918= | Silent (SNP) | VAF 462/1687 reads (27%) | called by muse, mutect2, varscan2
- KRTAP10-7 | c.996C>T p.T332= | Silent (SNP) | VAF 220/764 reads (29%) | catalogued as rs1485784015, COSV59109309; called by muse, mutect2, varscan2
- MAGEC3 | c.1458C>T p.V486= | Silent (SNP) | VAF 144/998 reads (14%) | called by muse, varscan2
- MS4A7 | c.531C>A p.T177= | Silent (SNP) | VAF 136/692 reads (20%) | called by mutect2, varscan2
- MUC16 | c.38136C>T p.Y12712= | Silent (SNP) | VAF 110/615 reads (18%) | catalogued as rs557724598, COSV67496475; called by muse, mutect2, varscan2
- MUC2 | c.2496C>T p.G832= | Silent (SNP) | VAF 234/1060 reads (22%) | catalogued as rs372733771; called by muse, mutect2, varscan2
- MUC5AC | c.15324G>A p.T5108= | Silent (SNP) | VAF 88/479 reads (18%) | catalogued as rs1387461108, COSV100611466; called by muse, mutect2, varscan2
- NFATC2 | c.1209T>C p.S403= | Silent (SNP) | VAF 332/1523 reads (22%) | called by muse, mutect2, varscan2
- NYX | c.531G>A p.A177= | Silent (SNP) | VAF 50/1042 reads (5%) | called by muse, mutect2
- PHIP | c.2404T>C p.L802= | Silent (SNP) | VAF 118/1746 reads (7%) | catalogued as rs1562156020; called by muse, mutect2
- SEMA5A | c.1095C>T p.Y365= | Silent (SNP) | VAF 220/1150 reads (19%) | catalogued as rs750122183; called by muse, mutect2, varscan2
- SHC1 | c.1365C>T p.P455= (on ENST00000368445 / NM_183001.5; = p.P346= on NM_003029.5) | Silent (SNP) | VAF 81/906 reads (9%) | called by muse, mutect2
- SLC17A5 | c.1377G>C p.V459= | Silent (SNP) | VAF 152/558 reads (27%) | called by muse, mutect2, varscan2
- SLITRK3 | c.1296T>C p.S432= | Silent (SNP) | VAF 239/1896 reads (13%) | catalogued as rs1253869911, COSV53850511; called by muse, mutect2, varscan2
- SPSB1 | c.552C>T p.D184= | Silent (SNP) | VAF 325/1066 reads (30%) | catalogued as rs548275117; called by muse, mutect2, varscan2
- USP6NL | c.633A>G p.K211= | Silent (SNP) | VAF 242/870 reads (28%) | catalogued as rs1047010737; called by muse, mutect2, varscan2
- ZNF81 | c.1488A>G p.K496= | Silent (SNP) | VAF 159/873 reads (18%) | called by muse, mutect2, varscan2
- ABHD5 | c.-26G>T | 5'UTR (SNP) | VAF 193/738 reads (26%) | called by muse, mutect2, varscan2
- AR | c.*24A>G | 3'UTR (SNP) | VAF 26/728 reads (4%) | called by muse, mutect2
- ARHGAP4 | c.2415-18C>T | Intron (SNP) | VAF 102/1148 reads (9%) | catalogued as rs782557710; called by muse, mutect2
- BARD1 | c.215+93T>G | Intron (SNP) | VAF 47/222 reads (21%) | called by muse, mutect2, varscan2
- BCORL1 | c.*3G>C | 3'UTR (SNP) | VAF 95/476 reads (20%) | called by muse, mutect2, varscan2
- C5orf15 | c.*73C>T | 3'UTR (SNP) | VAF 65/253 reads (26%) | called by muse, mutect2, varscan2
- CEP43 | c.301-88G>A | Intron (SNP) | VAF 14/200 reads (7%) | called by muse, mutect2
- EXOSC10 | c.1800+41G>A | Intron (SNP) | VAF 28/368 reads (8%) | called by muse, mutect2
- FLT3LG | c.-23G>C | 5'UTR (SNP) | VAF 111/545 reads (20%) | called by mutect2, varscan2
- IQCE | c.*20C>T | 3'UTR (SNP) | VAF 133/832 reads (16%) | catalogued as rs774489119, COSV100383709; called by muse, mutect2, varscan2
- KCTD1 | c.616-75T>A | Intron (SNP) | VAF 24/78 reads (31%) | called by muse, mutect2, varscan2
- KIAA1109 | c.11849-24A>T | Intron (SNP) | VAF 39/659 reads (6%) | called by muse, mutect2
- MICALL2 | c.2312-49G>A | Intron (SNP) | VAF 53/399 reads (13%) | called by muse, mutect2, varscan2
- MTO1 | c.1129+25C>T | Intron (SNP) | VAF 32/430 reads (7%) | called by muse, mutect2
- MTUS2 | c.3505+17T>A | Intron (SNP) | VAF 18/466 reads (4%) | called by muse, mutect2
- NUDT7 | c.-66C>G | 5'UTR (SNP) | VAF 144/450 reads (32%) | called by muse, mutect2, varscan2
- OR5R1 | chr11:56413363 C>T | 3'Flank (SNP) | VAF 40/1052 reads (4%) | called by muse, mutect2
- PDE4C | c.243-4122G>C | Intron (SNP) | VAF 106/543 reads (20%) | called by muse, mutect2, varscan2
- PSME4 | c.-14del | 5'UTR (DEL) | VAF 26/140 reads (19%) | catalogued as rs751997094; called by mutect2, varscan2
- RABGGTB | c.4-32A>G | Intron (SNP) | VAF 100/544 reads (18%) | called by muse, mutect2, varscan2
- STX18 | c.-71C>A | 5'UTR (SNP) | VAF 78/339 reads (23%) | called by muse, mutect2, varscan2
- TCEAL4 | c.-23+163G>T | Intron (SNP) | VAF 62/1125 reads (6%) | called by muse, mutect2
- TEX46 | c.3-36C>T | Intron (SNP) | VAF 78/360 reads (22%) | catalogued as rs528087534; called by muse, mutect2, varscan2
- TIMM17B | c.126+92G>A | Intron (SNP) | VAF 10/90 reads (11%) | catalogued as rs782044580; called by muse, mutect2
- TMEM213 | c.154+80G>A | Intron (SNP) | VAF 128/326 reads (39%) | catalogued as rs1045354955, COSV59478243; called by muse, mutect2, varscan2
- ZSCAN4 | c.*1G>A | 3'UTR (SNP) | VAF 146/654 reads (22%) | called by muse, mutect2, varscan2
